Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-6218, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-6218-01A (Primary Tumor).

[page 1 of 4]
Specimen(s) Received

1. Oral-Cavity: right tongue posterior margin
2. Oral Cavity: Rt buccal posterior lateral margin
3. Oral Cavity: Rt buccal anterior lateral margin
4. Oral Cavity: Rt floor of mouth/tongue double stitch -anterior; single stitch - middle
5. Oral Cavity: : Perifacial node - Rt side
6. Oral Cavity: Lt submandibular gland
7. Neck: Rt neck level 1
8. Neck: Rt neck level 2
9. Neck: Rt neck level 3
10. Oral Cavity: Rt perifacial node

Diagnosis

1. Right tongue posterior margin:
- Negative for malignancy.
2. Right buccal posterior lateral margin:
- Negative for malignancy.
3. Right buccal anterior lateral margin:
- Negative for malignancy.
4. Right floor of mouth/tongue; resection:
- Squamous cell carcinoma, moderately differentiated.
- a. Maximum tumour dimension 4.1 cm.
- b. Maximum tumour thickness 1.0 cm.
- c. Perineural invasion present.
- d. Tumour is close (0.4 cm) to the deep margin.
- e. All other margins, negative for tumour (≥ 0.5 cm).
5. Perifacial node; right side:
- One lymph node, negative for malignancy (0/1).
6. Left submandibular gland:

[page 2 of 4]
- Submandibular gland with no pathologic changes, negative for malignancy.
- 7. Right neck; level I:
- Submandibular gland with mild chronic inflammation, negative for malignancy.
- 8. Right neck; level II:
- Submandibular gland tissue and four lymph nodes, negative for malignancy (0/4).
- 9. Right neck; level III:
- Metastatic squamous cell carcinoma involving two of ten lymph nodes (2/10).
- a. Largest involved node is 1.5 cm.
- b. No extracapsular extension present.
- 10. Right perifacial node:
- One lymph node, negative for malignancy (0/1).

Synoptic Data

Specimen Type:	Resection: Right tongue.
Tumor Site:	Tongue
Histologic Type:	Squamous cell carcinoma, conventional
Tumor Size:	Greatest dimension: 4.1 cm
	Tumor thickness: 1.0 cm
Histologic Grade:	G2: Moderately differentiated
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L):	Absent
Perineural Invasion:	Present
Margins:	Margins uninvolved by tumor
	Margins uninvolved by tumor - Distance of tumor from closest margin: 0.4 cm
	Margins: Deep margin.
Pathologic Staging (pTNM):	pT3: Tumor or lip or oral cavity more than 4 cm in greatest dimension
	pN2b: Metastasis in multiple ipsilateral lymph nodes, none more than 6 cm in greatest dimension for all aerodigestive sites except nasopharynx
	Number of regional lymph nodes examined: 15
	Number of regional lymph nodes involved: 2
	Extra-capsular extension of nodal tumor: Absent
	pMX: Distant metastasis cannot be assessed

verified by: [REDACTED]

Electronically

[REDACTED]

Gross Description

1. The specimen labeled with the patient's name and as "Oral Cavity: Right tongue posterior margin, [REDACTED]" consists of a fragment of tissue that measures 0.7 x 0.4 x 0.2 cm. The specimen is frozen for intraoperative consultation.

1A- frozen section block resubmitted.

[page 3 of 4]
2. The specimen labeled with the patient's name and as "Oral Cavity: Right buccal posterior lateral margin" consists of a fragment of tissue that measures 0.9 x 0.5 x 0.1 cm. The specimen is frozen for intraoperative consultation.

2A- frozen section block resubmitted.

3. The specimen labeled with the patient's name and as "Oral Cavity: Right buccal anterior lateral margin" consists of a fragment of tissue that measures 0.7 x 0.5 x 0.1 cm. The specimen is frozen for intraoperative consultation.

3A- frozen section block resubmitted.

4. The specimen is labeled the patient's name and as "Oral Cavity: Right floor of mouth/tongue double stitch-anterior; single stitch-medial". It consists of a portion of right tongue measuring 3.3 cm SI x 4.5 cm ML x 5.1 cm AP. There are two sutures for orientation. There is a well-circumscribed tumor involving the lateral surface of the tongue and floor of mouth. The tumor measures 4.1 cm AP x 3.5 cm ML x 1.0 cm SI. The tumor is tan-brown in color and solid in consistency. It is located at in a 0.5 cm from the lateral margin, 0.5 cm from the medial margin, 0.7 cm from the deep margin, 0.5 cm from the anterior margin, and 0.6 from the posterior margin. The remaining tongue mucosa is unremarkable. Representative sections are submitted.

4A- anterior margin

4B- medial margin

4C- posterior margin

4D- lateral margin

4E-4I-tumor with deep margin

4J-normal tongue.

Four pieces of tumor were taken for tissue bank.

5. The specimen container is labeled with the patient's name and as "Oral Cavity: Perifacial node-right side". It consists of a piece of tissue measuring 1.2 x 1.2 x 0.5 cm

5A- specimen in toto.

6. The specimen container is labeled with the patient's name and as "Oral Cavity: Left submandibular gland". It consists of an unoriented submandibular gland with overall dimensions of 3.8 x 3.8 x 1.8 cm. The submandibular gland is unremarkable.

Representative sections are submitted

6A- submandibular gland.

7. The specimen labeled with the patient's name and as "Neck: Right neck level I" consists of a submandibular gland that measures 3.5 x 2.5 x 2.0 cm. The submandibular gland is unremarkable. Representative sections are submitted.

7A- submandibular gland

8. The specimen labeled with the patient's name and as "Neck: Right neck level II" consists of a piece of fibroadipose tissue that measures 3.0 x 2.0 x 1.3 cm and contains multiple lymph nodes that range from 0.5 to 1.2 cm. Representative sections are submitted.

8A- multiple lymph nodes.

9. The specimen labeled with the patient's name and as "Neck: Right neck level III" consists of a piece of fibroadipose tissue that measures 4.5 x 3.0 x 1.5 cm and contains multiple lymph nodes that range from 0.4 to 1.5 cm. Representative sections are submitted.

9A-9C- one lymph node each bisected.

9D- multiple lymph nodes.

10. The specimen container is labeled with the patient's name and as "Oral Cavity: Right perifacial node". It consists of a lymph node measuring 0.5 x 0.5 x 0.3 cm.

10A- specimen in toto.

[page 4 of 4]
[REDACTED]

Quick Section Diagnosis

1A. Oral-Cavity: right tongue posterior margin/[REDACTED] Negative for malignancy

Slides received at: [REDACTED]

Result reported at [REDACTED]

2A. Oral-Cavity: right buccal posterior lateral margin/[REDACTED] Negative for malignancy

Slides received at: [REDACTED]

Result reported at [REDACTED]

3A. Oral-Cavity: right buccal antero lateral margin/[REDACTED] Negative for malignancy

Slides received at: [REDACTED].

Result reported at [REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 544f95c9-d500-4fdb-902d-3a0118d14f1e (TCGA-CQ-6218.A771E4CD-3862-4C91-ACCC-914D4BE2E811.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).